Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3JH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3JH-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Metastatic melanoma - tumour bank.

(1) Tumour right axilla. (2) Small bowel tumour (distal).

(1) Small bowel anastomosis site. (2) Proximal small bowel tumour. (3) Proximal anastomosis small bowel.

NB: 2 other specimens sent to tumour bank.

Metastatic melanoma.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking

MACROSCOPIC DESCRIPTION

Five specimens received.

1. "LYMPH NODE RIGHT AXILLA". Specimen is a firm nodule with an attached, small amount of fat, specimen measures 50 x 45 x 30mm. Tissues have been taken for tumour banking and specimen is inked blue. On serial sectioning cut surface appears greyish brown and nodular. Tumour abuts blue inked margin. Six representative sections from tumour are embedded from Block 1A-1F.

2. "SMALL BOWEL". Specimen consists of a section of small bowel, received unopened. The bowel measures from superior to inferior 145mm with an opened diameter of 70mm. The attached mesentery is 65mm wide, the external surface of bowel is grey and dull with a mass palpable under the serosal surface. The mucosal surface of bowel shows a fungating polypoidal and ulcerating tumour which is 40mm away from blue inked margin, and 75mm away from black inked margin. Tumour is 30mm away from nearest radial resection margin. Tumour measures 45 x 35 x 20mm and involves the whole thickness of bowel, and penetrating into adjacent fat.

2A. Blue resection margin.

2B. Black resection margin.

2C, 2D, 2E & 2F. Representative sections from tumour showing relationship with mucosal surface serosa and adjacent fat.

2G. One apical node trisected.

2J.-P **Sampling fat for possible lymph nodes**

3. "SMALL BOWEL ANASTOMOSIS SIDE". Specimen consists of a small section of bowel, measuring 7mm in length with a closed diameter of 32mm. Staples removed and specimen embedded in Blocks 3A-3D.

4. "PROXIMAL SMALL BOWEL TUMOUR". Specimen consists of a segment of bowel, measuring 105mm in length with a closed diameter of 55mm. There is attached fatty tissue, measuring 5mm wide. The serosal surface is dull and grey. The mucosal surface shows a fungating ulcerating necrotic tumour measuring 75 x 65 to a height of 15mm. This tumour is 12mm away from blue inked margin, and 20mm away from black inked margin. On cut section the tumour involves entire thickness of bowel wall and penetrates into adjacent fat with extensive necrotic areas.

Printer

[page 2 of 2]
Requested by

Accession:

HISTOPATHOLOGY REPORT

- 4A. Blue inked margin.
4B. Black inked margin.
4C-4G. Representative section of tumour showing relationship with mucosa, serosa and adjacent bowel.
4H. sampling fat for possible nodes

5. "PROXIMAL ANASTOMOSIS SMALL BOWEL". Specimen consists of a small section of bowel, 15mm long with a close diameter of 30mm. staples removed. Representative section embedded from Block 5A to 5D. 50% of specimen embedded.

MICROSCOPIC REPORT

1. "LYMPH NODE RIGHT AXILLA". Sections confirm the presence of metastatic melanoma which essentially replaces the lymph node. Focal extranodal extension is seen, where tumour extends to within 0.2mm of the blue inked resection margin. Stains for melanoma markers (HMB45, S-100 and MelanA) are diffusely and strongly positive.
2. "SMALL BOWEL". Sections confirm the presence of metastatic melanoma (melanoma markers are diffusely positive) which forms a large nodule eroding the overlying small bowel mucosa and extending into the subserosal fat. The margins appear clear. The small bowel mucosa away from the tumour shows intact villous architecture. One lymph node is identified at the apex which contains pigmented histiocytes but no evidence of metastatic melanoma.
3. "SMALL BOWEL ANASTOMOSIS SIDE". Sections of small intestine show viable tissue with no evidence of malignancy.
4. "PROXIMAL SMALL BOWEL TUMOUR". Sections again show an epithelioid tumour consistent with metastatic melanoma, with an admixed lymphocytic infiltrate. The lesion ulcerates the small bowel mucosa and extends to involve the full thickness of the wall of the bowel. The resection margins appear clear. No lymph nodes are identified.
5. "PROXIMAL ANASTOMOSIS SMALL BOWEL". Sections of small intestine show viable tissue with no evidence of malignancy.

SUMMARY

1. "LYMPH NODE RIGHT AXILLA". Metastatic melanoma
/
2. "SMALL BOWEL". Metastatic melanoma
/
3. "SMALL BOWEL ANASTOMOSIS SIDE". No evidence of malignancy
/
4. "PROXIMAL SMALL BOWEL TUMOUR". Metastatic melanoma
/
5. "PROXIMAL ANASTOMOSIS SMALL BOWEL". No evidence of malignancy

REPORTED BY

Source: NCI Genomic Data Commons file 7657c2e0-f6a6-422c-aeae-770638fa7763 (TCGA-EE-A3JH.0ABDF8B5-C0D2-4F4A-8BE1-B8FA03F0026C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).